Surgical pathology report (de-identified scan), TCGA case TCGA-D9-A3Z3, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D9-A3Z3-06A (Metastatic).

Department of Cancer Pathology

Patient: XXX : XXX Age: Gender:

Examination result

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion): : Melanoma malignum cutis typ SSM sine ulceratione. State after resection
Metastases to lymph nodes of the right axilla

Date of admission: (urgency: Standard)

Material:

1) Material: lymph node - axillary lymph nodes. Method of collection: Total organ resection

Histopathological diagnosis:

Examination performed on

Melanoma metastases to axillary lymph nodes (1/10): metastasis diameter 0.5cm.

Macroscopic description:

Lymph nodes of 2.0 cm in length.

Assistant:

Pathologist: :

Edited by

CONTACT YOUR DOCTOR WITH THIS REPORT!

ICD-O-3

melanoma, NOS

8720/3

Site: lymph node, axillary

C77.3

6-6-12
PD

Review Initial	6/6/12	6/6/12

Source: NCI Genomic Data Commons file cc9351a7-65de-4077-b75c-8ef33f00755c (TCGA-D9-A3Z3.29C111B1-5E65-4CCE-A513-D40CF02069E9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).